Somatic mutation profile of tumor specimen TCGA-OR-A5LA-01A (aliquot TCGA-OR-A5LA-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LA, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 52.7 years (19,242 days).
Specimen TCGA-OR-A5LA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6e8936a-e949-4dc0-a592-ea4148aacb5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LA-10A (Blood Derived Normal), aliquot TCGA-OR-A5LA-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a0ca4df-bd3c-4c70-9c51-ae249e36f833

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM170A | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs369994686; called by muse, mutect2, varscan2
- ALOX12 | c.809A>G p.N270S | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.065); called by muse, mutect2
- BCL2L1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- GET4 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OPA1 | c.2577G>T p.E859D (on ENST00000361510 / NM_130837.3; = p.E804D on NM_015560.3) | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP34 | c.6938T>G p.L2313R | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CALHM6 | c.471G>A p.Q157= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- AL136982.4 | n.677C>T | RNA (SNP) | VAF 25/586 reads (4%) | called by muse, mutect2
